Surgical pathology report (de-identified scan), TCGA case TCGA-NJ-A4YF, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Rush University, specimen TCGA-NJ-A4YF-01A (Primary Tumor).

[page 1 of 10]
1

Procedure Location:

1CD-0-3

Path: adenocarcinoma, NOS 8140/3

CQCF: adenocarcinoma, w/ mixed subtypes 8355/3

Site: lung, ^(R)upper lobe C34.1

hw
10/31/12

PATHOLOGY SURGICAL

Results

[page 2 of 10]
Entry Date

Component Results

PATHOLOGY RESULT:

Department of Pathology

* Amended *

Clinical Data Repository* This report may not match the original report
format

[page 3 of 10]
AMENDMENTS

FINAL DIAGNOSIS

A. (Pleura, biopsy): Skeletal muscle and fibrous tissue with chronic inflammation. No tumor seen.

B. (Right upper lobe, lobectomy): Poorly differentiated adenocarcinoma, measuring 2.5cm in the greatest dimension, focally extending into the visceral pleura.

Bronchial, vascular, and stapled surgical margins are free of tumor.

Remaining lung with mild emphysema and chronic inflammation.

pT2N0Mx

C. (Level 11 lymph node, biopsy): Lymph nodes with anthracosis.

D. (Level 7 lymph node, biopsy): Lymph nodes with anthracosis.

[page 4 of 10]
E. (Level 4/2 lymph node, biopsy): Fibroadipose tissue and minute fragment of lymphoid tissue with anthracosis.

F. (Level #8, biopsy): Fibrous tissue and blood.

INTRAOPERATIVE CONSULTATION

A. FROZEN: PLEURAL BIOPSY CANCER OR NO CANCER: Skeletal muscle and fibroconnective tissue with focal chronic inflammation. No tumor seen.
(Frozen section and touch preps reviewed).

B. FROZEN: RIGHT UPPER LOBE FROZEN SECTION ON BRONCHIAL MARGINS:
Adenocarcinoma. Bronchial margin negative for tumor. (Frozen sections and touch preps reviewed).

[page 5 of 10]
GROSS DESCRIPTION

A. The specimen, submitted for frozen section, is labeled pleural biopsy.

Received fresh is a 0.3 x 0.3 x 0.2 cm aggregate of soft pink tissue. Touch preps are prepared. The entire specimen is submitted for frozen section with the remnants placed in cassette A91.

B. The specimen, submitted for frozen section, is labeled right upper lobe.

Received fresh is a 17.0 x 12.0 x 5.0 cm right upper lobe of lung. There is a palpable peripheral mass with puckering of the overlying pleura. The pleura overlying the mass is inked blue and the lung is serially sectioned to show a 2.5 x 1.5 x 1.5 cm irregular tan nodule. Touch preps of the mass are prepared. The bronchial margin and a section of the mass are submitted for frozen section with the remnants placed in cassettes B91 and B92 respectively.

No other masses or lesions are identified in the lung. Representative sections are submitted as follows: B1 - vascular margin; B2 and B3 - stapled surgical margin; B4 through B6 - sections of the nodule; B7 - section of uninvolved lung.

C. The specimen is labeled level 11 lymph node. Received fresh is a 2.0 x 1.5 x 0.8 cm aggregate of soft pink to black tissue. The entire specimen is

[page 6 of 10]
serially sectioned and submitted in cassette C1.

D. The specimen is labeled level 7 lymph node. Received fresh is a 1.5 x 1.0 x 0.6 cm aggregate of soft tan to black tissue. The entire specimen is submitted in cassette D1.

E. The specimen is labeled level 4/2 lymph node. Received fresh is a 1.0 x 1.0 x 0.2 cm aggregate of soft pink tissue. The entire specimen is submitted in cassette E1.

F. The specimen is labeled level 8. Received fresh is a 0.3 x 0.2 x 0.2 cm fragment of soft pink tissue. The entire specimen is wrapped and submitted in cassette F1.

SPECIMEN(S) RECEIVED

A: FROZEN: PLEURAL BIOPSY CANCER OR NO CANCER

B: FROZEN: RIGHT UPPER LOBE FROZEN SECTION ON BRONCHIAL MARGINS

C: LEVEL 11 LYMPH NODE

D: LEVEL 7 LYMPH NODE

E: LEVEL 4/2 LYMPH NODE

F: LEVEL #8

*** The above listed tests (if any) were developed and the performance**

characteristics determined by

These tests have

[page 7 of 10]
not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays.

OPERATIVE INFORMATION

Diagnosis: Right upper lobe mass

Procedure: Thoracoscopy video assisted, thoracotomy wedge resection,
bronchoscopy flexible fiberoptic

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s):

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Lab and Collection

[page 8 of 10]
PATHOLOGY SURGICAL

b and Collection Information

Result History

Order Result History Report

Pathology

[page 9 of 10]
Procedure Location:

Dx discrepancy form attached.

[illegible]

[page 10 of 10]
TCGA Pathologic Diagnosis Discrepancy Form

V1.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS) _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Poorly Differentiated Adenocarcinoma focally extending into visceral pleura.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Mixed: acinar, solid	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Path report does not subtype.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Date

Source: NCI Genomic Data Commons file 938987e9-d245-4f60-8f6b-af4864214303 (TCGA-NJ-A4YF.1C272E41-4BE4-4E8A-BD33-A5EC5C33149C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).